TCGA case TCGA-06-0681 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Brain; Tissue source site: Henry Ford Hospital.
https://portal.gdc.cancer.gov/cases/680b2e96-f00b-4012-8728-b0ec20c50ce0

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0681-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-0681-11A-04-TS4: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 75; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
